Surgical pathology report (de-identified scan), TCGA case TCGA-XM-A8RH, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-A8RH-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] (Age: F Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:

Supraclavicular LAD. CT showing anterior mediastinal mass consistent with thymoma.

Specimens Submitted:
1: Thymus (fs)

DIAGNOSIS:

1. Thymus; resection (fs):
- Thymoma, WHO type B1.
- Tumor size: 4.5 cm.
- The tumor focally extends through the capsule into fibroadipose/thymic tissue.
- Margins are free of tumor.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "Thymus", and consists of a portion of thymus measuring 9.3 x 6.4 x 2.6 cm overall. The thymus is tan-yellow and lined by a thin fibrous layer. There is a 4.5 x 3.5 x 3.0 well circumscribed tan-white mass identified on the outer aspect of the thymus. The mass is previously inked blue. Sectioning of the mass reveals a tan-white lobular cut surface. The mass does not grossly invade into the thymus. The remaining thymus has a yellow lobular, glandular cut surface. Representative sections are submitted. TPS and

** Continued on next page **

ICD O-3
Thymoma, type B1, malignant
858313
Site: Thymus
037.9
7/3/12/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #: [REDACTED]
Physician: [REDACTED]
Service: [REDACTED]
Date of Report: [REDACTED]

----- Page 2 of 2
gross photographs are taken.

Summary of sections:
MT--mass with attachment thymus

Summary of Sections:
Part 1: Thymus (fs)

Blocks	Block Designation	PCs
1	{not entered}	
3	M 3	
3	MT 3	
2	RT 4	

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: Consistent with thymoma.
PERMANENT DIAGNOSIS: Same

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: Consistent with thymoma.
PERMANENT DIAGNOSIS: Same

** End of Report **

Source: NCI Genomic Data Commons file 8128894a-4071-4739-ba6d-6696a83fdc67 (TCGA-XM-A8RH.EDFCC5C9-4CA4-4AC6-88DE-CA69BD3BE1BF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).